Somatic mutation profile of tumor specimen TCGA-DC-5869-01A (aliquot TCGA-DC-5869-01A-01D-1657-10) from TCGA case TCGA-DC-5869, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 62.1 years (22,676 days).
Specimen TCGA-DC-5869-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee5a15b4-c12f-4d38-bbc8-b13c97ade139.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DC-5869-10A (Blood Derived Normal), aliquot TCGA-DC-5869-10A-01D-1657-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab00fca7-41c5-4073-b1dd-eeddf51c323b

The open-access MAF lists 77 somatic variants for this specimen: 53 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 48, Silent 24, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.773A>G p.E258G | Missense Mutation (SNP) | VAF 46/68 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1060501201, COSV52661460, COSV52665450, COSV52688395, COSV53578543; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCE1 | c.356C>G p.A119G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99668291; called by muse, mutect2, varscan2
- AFF2 | c.820C>A p.L274I | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV100648677, COSV60663667; called by muse, mutect2, varscan2
- ARHGAP36 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.127); catalogued as rs368664815, COSV52268214, COSV52270111; called by muse, mutect2, varscan2
- ASB17 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99407765; called by muse, varscan2
- BNC1 | c.2375G>A p.R792H | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1340436632, COSV61758585; called by muse, mutect2, varscan2
- CADPS2 | c.1179A>C p.E393D | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.97); catalogued as COSV57377154; called by muse, mutect2
- CDK5 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs1186998547, COSV52524827; called by muse, mutect2, varscan2
- CHGA | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs780810744, COSV99380942; called by muse, mutect2, varscan2
- DRD3 | c.383+1G>A p.X128_splice | Splice Site (SNP) | VAF 12/29 reads (41%) | catalogued as rs770828404, COSV55682050, COSV99879060; called by muse, varscan2
- DYNC1H1 | c.7554C>G p.I2518M | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as rs1172501503, COSV64140266; called by muse, mutect2, varscan2
- FBXW7 | c.1738C>T p.H580Y (on ENST00000281708 / NM_001349798.2; = p.H500Y on NM_018315.5) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55895792, COSV55902357; called by muse, mutect2, varscan2
- FBXW7 | c.1327C>T p.L443F (on ENST00000281708 / NM_001349798.2; = p.L363F on NM_018315.5) | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55968750; called by muse, mutect2, varscan2
- FOS | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57839514; called by muse, mutect2, varscan2
- GABRA5 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59483674; called by muse, mutect2, varscan2
- HUWE1 | c.5359C>T p.R1787W | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782600084, COSV53358065; called by muse, mutect2, varscan2
- IRF1 | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99810333; called by muse, mutect2, varscan2
- ITIH6 | c.3349G>T p.A1117S | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.677); catalogued as COSV54492417; called by muse, mutect2, varscan2
- KAZN | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.492); catalogued as rs761787678, COSV65714155, COSV65723252; called by muse, mutect2, varscan2
- KCNA5 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770186331, COSV52904821; called by mutect2, varscan2
- KDM2B | c.2749G>A p.A917T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV65638883; called by muse, mutect2, varscan2
- KDM5A | c.1902G>A p.M634I | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1279549290, COSV66995090; called by muse, mutect2, varscan2
- KIRREL2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs571708243, COSV52874405; called by muse, mutect2, varscan2
- MAGEC3 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.029); catalogued as COSV68924099; called by muse, varscan2
- MAGEC3 | c.1400T>A p.L467H | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53581041, COSV68924122; called by muse, varscan2
- MAST3 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53217754; called by muse, varscan2
- MORC1 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs759790452, COSV51713109; called by muse, mutect2, varscan2
- MTMR1 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as rs782762145, COSV100953041, COSV100953157; called by muse, mutect2, varscan2
- NHSL2 | c.1513G>A p.V505I (on ENST00000510661; = p.V871I on NM_001013627.2) | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as rs138074424, COSV65454398; called by muse, mutect2, varscan2
- PABPN1L | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs760201583, COSV99967445; called by mutect2, varscan2
- PARP8 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.133); catalogued as COSV55864271; called by muse, mutect2, varscan2
- PCDHGA8 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53907990; called by muse, mutect2, varscan2
- PHACTR3 | c.488A>G p.D163G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs745894750, COSV100732130; called by mutect2, varscan2
- PLCG1 | c.308A>T p.Q103L | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99718326; called by muse, mutect2
- RET | c.983C>G p.T328S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.08); catalogued as rs948303275, COSV100391857; called by muse, mutect2, varscan2
- SCUBE1 | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs550015784, COSV62614921; called by muse, varscan2
- SETX | c.6949G>T p.V2317F | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.438); catalogued as COSV56391308; called by muse, mutect2
- ST8SIA6 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs1368986000, COSV101112242, COSV66467127; called by muse, mutect2, varscan2
- TBC1D10C | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs771396666, COSV56704417; called by muse, mutect2, varscan2
- TEX37 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.93); catalogued as COSV57556489; called by muse, mutect2
- TIAM1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.75); catalogued as rs371530269; called by muse, mutect2, varscan2
- TRPM1 | c.3368G>A p.R1123H | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as rs200369359, COSV99855091; called by muse, mutect2, varscan2
- UNC13C | c.4027C>T p.R1343* | Nonsense Mutation (SNP) | VAF 38/147 reads (26%) | catalogued as rs748266855, COSV52849771; called by muse, mutect2, varscan2
- UTRN | c.1205A>G p.E402G | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62334667; called by muse, mutect2, varscan2
- ZNF267 | c.1525C>A p.Q509K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56255052; called by mutect2, varscan2
- ZNF684 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs201288463, COSV65518951, COSV65519474; called by muse, mutect2, varscan2
- ZNF804B | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766134214, COSV100301117; called by mutect2, varscan2
- ZZEF1 | c.539A>G p.D180G | Missense Mutation (SNP) | VAF 64/78 reads (82%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371226804; called by muse, mutect2, varscan2
- APC | c.1918_1921del p.R640Mfs*5 | Frame Shift Del (DEL) | VAF 55/116 reads (47%) | called by mutect2, pindel, varscan2
- C1orf109 | c.260A>G p.K87R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.202); called by muse, mutect2
- OBSL1 | c.2210C>T p.T737I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.426); called by muse, mutect2
- TOPBP1 | c.600_603del p.F200Lfs*4 | Frame Shift Del (DEL) | VAF 25/109 reads (23%) | called by mutect2, pindel, varscan2
- TRMT11 | c.167C>A p.S56Y | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); called by muse, mutect2
- AKR1B1 | c.111C>T p.D37= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs758567690, COSV53648400; called by muse, mutect2, varscan2
- DGKK | c.3810A>G p.Q1270= | Silent (SNP) | VAF 56/100 reads (56%) | catalogued as rs782814569, COSV101052836; called by muse, mutect2, varscan2
- DNAH1 | c.8994G>A p.K2998= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV70233349; called by muse, mutect2, varscan2
- DOCK9 | c.1302G>A p.A434= (on ENST00000376460 / NM_001366676.2; = p.A435= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs1265110527, COSV59637131; called by muse, mutect2, varscan2
- DYSF | c.1449G>A p.S483= | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as rs755103680, COSV50267426; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EBF1 | c.1443T>C p.Y481= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100564917; called by muse, mutect2, varscan2
- FAM47B | c.465C>T p.P155= | Silent (SNP) | VAF 73/120 reads (61%) | catalogued as rs780401613, COSV61452745, COSV61455558; called by muse, mutect2, varscan2
- FER1L6 | c.5496C>T p.I1832= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV67551911; called by muse, mutect2
- GPR152 | c.933G>A p.S311= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs148579956; called by muse, mutect2, varscan2
- LEMD3 | c.1422G>A p.S474= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV57650087; called by muse, mutect2, varscan2
- LRRN1 | c.1098C>A p.I366= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100075905; called by muse, mutect2, varscan2
- MRGPRF | c.855C>T p.S285= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs1349301695, COSV57996325; called by muse, mutect2, varscan2
- PILRB | c.9G>C p.R3= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as COSV60335655; called by muse, varscan2
- PKM | c.930G>A p.Q310= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV100064276; called by muse, mutect2, varscan2
- PPP1R12C | c.801G>A p.A267= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs757621931, COSV54739245; called by muse, mutect2, varscan2
- ROBO1 | c.4302G>A p.A1434= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as rs558087386, COSV71397175; called by muse, mutect2, varscan2
- SETX | c.6951T>C p.V2317= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV99808457; called by muse, mutect2
- SH3BP4 | c.2316C>T p.F772= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs1468602238, COSV100748946; called by muse, mutect2, varscan2
- SH3RF3 | c.996C>T p.A332= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs537361444, COSV58691841; called by muse, mutect2, varscan2
- SPTA1 | c.6459C>A p.V2153= | Silent (SNP) | VAF 47/75 reads (63%) | catalogued as COSV100933978, COSV63757978; called by muse, mutect2, varscan2
- TNR | c.1710C>T p.Y570= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as rs746969510, COSV54899996; called by muse, mutect2, varscan2
- UNC79 | c.4374C>T p.S1458= (on ENST00000393151 / NM_001346218.2; = p.S1281= on NM_020818.5) | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs777066349, COSV56399861; called by muse, mutect2
- VWF | c.4659C>T p.S1553= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs375675510; called by muse, mutect2, varscan2
- WIPF1 | c.618G>T p.V206= | Silent (SNP) | VAF 42/58 reads (72%) | catalogued as rs762372137, COSV55818542; called by muse, mutect2, varscan2
